TCGA case TCGA-06-0176 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7391f99d-9528-46a1-9799-c5f0a7bfc63e

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 34 years; Vital status: Alive.

Diagnoses (3)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 35.0 years (12,777 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 50 days; Days to treatment end: 93 days; Treatment dose: 6,000 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 50 days; Days to treatment end: 93 days; Number of cycles: 1; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 127 days; Days to treatment end: 584 days (1.6 years); Number of cycles: 12; Treatment dose: 400 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 35.1 years (12,818 days); Days to diagnosis: 41 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
3. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 35.1 years (12,818 days); Days to diagnosis: 41 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 41 (post initial treatment): Progression or recurrence: Yes; Days to progression: 41 days.
- Days to follow up: 1,562 days (4.3 years); Disease response: Tumor Free.
- Days to follow up: 2,768 days (7.6 years); Disease response: Tumor Free.
- Karnofsky performance status: 80; Timepoint: Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0176-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.6; Intermediate dimension: 0.9; Shortest dimension: 0.9.
  Slide TCGA-06-0176-01A-01-BS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 40; Percent stromal cells: 5.
  Slide TCGA-06-0176-01A-02-BS2: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 0.
  Slide TCGA-06-0176-01A-03-BS3: Section location: Bottom; Percent tumor cells: 55; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 45; Percent stromal cells: 0.
- Sample TCGA-06-0176-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-0176-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: Tumor free; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Regimen number: 01.
- Drug treatment 1, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,768 days; disease-specific survival: no event (censored), 2,768 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 41 days.
